Somatic mutation profile of tumor specimen TCGA-CV-A464-01A (aliquot TCGA-CV-A464-01A-11D-A25Y-08) from TCGA case TCGA-CV-A464, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 48.4 years (17,669 days).
Specimen TCGA-CV-A464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38154a0b-d2d0-4034-af73-56c279268291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A464-10A (Blood Derived Normal), aliquot TCGA-CV-A464-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad4134b4-63f4-4fa5-9c97-5db1b3fefe9c

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 12, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CACNA1G | c.4349C>A p.T1450N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100662247; called by muse, mutect2, varscan2
- CASKIN2 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868219326, COSV58594942; called by muse, mutect2
- COL12A1 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs772210650, COSV59389973; called by muse, mutect2
- CRACDL | c.1142G>A p.C381Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1174473494, COSV101194102; called by muse, mutect2, varscan2
- CYYR1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1436745798, COSV100177357; called by muse, mutect2
- DHX57 | c.2586G>T p.M862I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV99769784; called by muse, mutect2, varscan2
- H2BC13 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as COSV100704419; called by muse, mutect2, varscan2
- IHH | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs3731880; called by muse, mutect2, varscan2
- KCNA5 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV52904944; called by muse, mutect2, varscan2
- NGEF | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99890192; called by muse, mutect2, varscan2
- NRAP | c.4900G>A p.D1634N (on ENST00000359988 / NM_001322945.2; = p.D1599N on NM_006175.4) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs560981716, COSV63490160; called by muse, mutect2, varscan2
- PIK3CG | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100782799, COSV100783044; called by muse, mutect2, varscan2
- PTPN12 | c.695+1G>T p.X232_splice | Splice Site (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99950587; called by muse, mutect2, varscan2
- SLC4A5 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697881; called by muse, mutect2
- ZBTB33 | c.595T>A p.S199T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100434265; called by muse, mutect2, varscan2
- ARNT2 | c.1620A>T p.S540= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV100309312, COSV57588278; called by muse, mutect2, varscan2
- DOCK1 | c.486G>A p.L162= | Silent (SNP) | VAF 15/153 reads (10%) | catalogued as COSV99731579; called by muse, mutect2
- GNPAT | c.186A>T p.G62= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100791671; called by muse, mutect2, varscan2
- H1-10 | c.606G>A p.K202= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1344504265, COSV100412954; called by muse, mutect2
- HDC | c.283C>T p.L95= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs780891675, COSV99984223; called by muse, mutect2, varscan2
- HSCB | c.642T>C p.I214= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as COSV99319754; called by muse, mutect2, varscan2
- PLXNA3 | c.1107G>A p.L369= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV100860145; called by muse, mutect2, varscan2
- SIGLEC12 | c.846C>T p.T282= (on ENST00000291707 / NM_053003.4; = p.T164= on NM_033329.2) | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as rs866507455; called by muse, mutect2
- STON2 | c.2292G>A p.L764= (on ENST00000649389 / NM_001366849.2; = p.L707= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as COSV99965002; called by muse, mutect2, varscan2
- TBL1Y | c.123G>T p.G41= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100667319; called by muse, mutect2, varscan2
- TCHH | c.4236C>T p.R1412= | Silent (SNP) | VAF 34/187 reads (18%) | catalogued as rs752898011, COSV100915303; called by muse, mutect2, varscan2
- ZC3H7B | c.1242C>T p.P414= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100687607; called by muse, mutect2, varscan2
- OR2U1P | n.381T>A | RNA (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
